Somatic mutation profile of tumor specimen MP2PRT-PAUNBV-TMP1-A (aliquot MP2PRT-PAUNBV-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUNBV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,016 days).
Specimen MP2PRT-PAUNBV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a72d366-2c35-48fa-a4fe-832b9d3e4932.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUNBV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUNBV-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca0f9753-06f1-496e-bf54-1c5b09ebfa9d

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, RNA 1, Intron 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGF3 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 292/963 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.17); catalogued as rs782047997; called by muse, mutect2, varscan2
- KCTD8 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 198/779 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1347768461; called by muse, varscan2
- NLRP9 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 85/379 reads (22%) | catalogued as rs758128073, COSV60463249; called by muse, mutect2, varscan2
- PAFAH2 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 72/366 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs796682047, COSV65339887; called by muse, mutect2, varscan2
- PIGL | c.438C>G p.F146L | Missense Mutation (SNP) | VAF 123/311 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56686910; called by muse, mutect2, varscan2
- RSPH10B2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 156/476 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs767769813, COSV51870745; called by muse, varscan2
- NUAK1 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 82/377 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RP9 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 178/443 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC102A | c.1110C>T p.G370= | Silent (SNP) | VAF 259/608 reads (43%) | called by muse, mutect2, varscan2
- CDH20 | c.1152C>T p.D384= | Silent (SNP) | VAF 183/695 reads (26%) | catalogued as rs758261493, COSV53011748; called by muse, mutect2, varscan2
- MYO1C | c.1914C>T p.D638= (on ENST00000648651 / NM_001080779.2; = p.D603= on NM_033375.5) | Silent (SNP) | VAF 135/370 reads (36%) | catalogued as rs527860096, COSV62998406; called by muse, mutect2, varscan2
- RNF144B | c.723G>A p.R241= | Silent (SNP) | VAF 94/390 reads (24%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.87C>T p.F29= | Silent (SNP) | VAF 139/330 reads (42%) | called by muse, mutect2, varscan2
- CDKN2B | c.156+17G>A | Intron (SNP) | VAF 274/693 reads (40%) | catalogued as rs777390916, COSV52805307; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442816 C>T | 3'Flank (SNP) | VAF 71/201 reads (35%) | catalogued as rs769213511, COSV100678994; called by muse, mutect2, varscan2
- REXO1L1P | n.835C>T | RNA (SNP) | VAF 82/1246 reads (7%) | catalogued as rs764204507; called by muse, mutect2
